CCDI case PAUTVR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/6e2bd2af-4c0d-4141-a156-bc402752b50b

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.6 years (577 days).

Biospecimens (3 samples)
- Sample 0DXH9I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXH9M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXHA8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
